CCDI case PBBTTX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/6b5d0972-77e7-4970-9aa6-11727b45e138

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 2.8 years (1,029 days).

Biospecimens (2 samples)
- Sample 0DGUSA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGUTB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
